Somatic mutation profile of tumor specimen 1105194 (aliquot 7316UP-181-1105194) from CPTAC case C234192, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105194: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53470318-ef25-4fe4-ba7f-d774653dd017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105286 (Blood Derived Normal), aliquot 7316UP-386-1105286; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/063c27f4-d31d-472f-82ee-4498f1b88bb6

The open-access MAF lists 106 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 22, Intron 9, Frame Shift Del 5, Nonsense Mutation 4, Splice Region 3, 3'Flank 3, Splice Site 2, Frame Shift Ins 2, 3'UTR 2, 5'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1B10 | c.742-7C>T | Splice Region (SNP) | VAF 80/405 reads (20%) | catalogued as rs766204329; called by muse, mutect2, varscan2
- AL592490.1 | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs775154689; called by muse, mutect2, varscan2
- CCDC144A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1365470382, COSV100501884; called by muse, mutect2, varscan2
- CDC7 | c.450_454del p.F151Rfs*8 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs752362072; called by pindel, varscan2
- DSCAML1 | c.5677G>A p.E1893K (on ENST00000321322; = p.E1833K on NM_020693.4) | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208211363; called by muse, mutect2, varscan2
- EAF2 | c.736+4_736+7del p.X246_splice | Splice Site (DEL) | VAF 20/66 reads (30%) | catalogued as rs767640852; called by pindel, varscan2
- EBPL | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.796); catalogued as rs200901347, COSV54431481; called by mutect2, varscan2
- FZD9 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs547599913; called by muse, mutect2
- GK2 | c.117C>A p.H39Q | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV62627486; called by muse, mutect2, varscan2
- GPATCH8 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 64/357 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59195790, COSV59196909; called by muse, mutect2, varscan2
- IGHA1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 134/414 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs753985358; called by muse, mutect2, varscan2
- IGHG2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 162/482 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs762234471; called by muse, mutect2, varscan2
- ITGAM | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.18); catalogued as rs755777607, COSV54933096; called by muse, mutect2, varscan2
- KCNE1 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs142511345, CM097709; ClinVar: not provided / likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- LCN10 | c.536C>T p.A179V (on ENST00000474369 / NM_001368089.1; = p.A192V on NM_001001712.3) | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs751195542; called by muse, mutect2, varscan2
- MAPK15 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 88/249 reads (35%) | catalogued as rs782012920; called by muse, mutect2, varscan2
- MUC16 | c.12422G>T p.G4141V | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1018086393; called by muse, mutect2, varscan2
- NLRP5 | c.62+1G>A p.X21_splice | Splice Site (SNP) | VAF 38/177 reads (21%) | catalogued as rs199475763; ClinVar: not provided; called by muse, mutect2, varscan2
- OR14A2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs779547225; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, mutect2, varscan2
- PCDHGC5 | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs867069360; called by muse, mutect2
- PPARGC1B | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 157/384 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs753410582; called by muse, mutect2, varscan2
- PTEN | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64307058; called by muse, mutect2, varscan2
- RDH10 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 181/538 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs190882720, COSV53582156; called by muse, mutect2, varscan2
- SH3RF2 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182882077; called by muse, mutect2, varscan2
- SLC1A6 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 124/491 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1026402297, COSV55673390, COSV99693589; called by muse, mutect2, varscan2
- SSUH2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs147081374; called by muse, mutect2, varscan2
- STK32C | c.1119C>T p.N373= | Splice Region (SNP) | VAF 68/116 reads (59%) | catalogued as rs745931599; called by muse, mutect2, varscan2
- TIMD4 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 119/313 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779272298; called by muse, mutect2, varscan2
- TOR4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62627636; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2, varscan2
- WWC2 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1237914404; called by muse, mutect2, varscan2
- ZBTB39 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 113/291 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as COSV55630225; called by muse, mutect2, varscan2
- ZNF578 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 32/486 reads (7%) | catalogued as rs767983794, COSV69737570; called by muse, mutect2
- ZNF804A | c.51C>G p.H17Q | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373088099; called by muse, varscan2
- ZP2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs558301595, COSV54814788; called by muse, mutect2, varscan2
- ADAMTS16 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ADRA2C | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARFGEF3 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRAT1 | c.2339A>G p.D780G | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH12 | c.3374G>T p.S1125I (on ENST00000351747; = p.S1148I on NM_001366028.2) | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DST | c.21967dup p.S7323Ffs*53 (on ENST00000361203 / NM_001374722.1; = p.S4996Ffs*22 on NM_015548.5) | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- FASLG | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GNAQ | c.397_400del p.K133Vfs*34 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel, varscan2
- GNL2 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNT2 | c.3370G>A p.V1124I | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KHSRP | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- MANSC1 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- MAP2 | c.4276A>G p.R1426G | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, varscan2
- MAP2 | c.4316C>T p.S1439F | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- PCYT1A | c.123dup p.R42Tfs*8 | Frame Shift Ins (INS) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- RLF | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RNF17 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPL5 | c.23_25delinsTT p.K8Ifs*11 | Frame Shift Del (DEL) | VAF 63/203 reads (31%) | called by pindel, varscan2*
- SAMM50 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC6A17 | c.299del p.V100Gfs*7 | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | called by mutect2, pindel, varscan2
- SYTL2 | c.1092G>C p.L364F | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TMEM132C | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTK | c.2310T>C p.C770= | Splice Region (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- UBN1 | c.1384_1385del p.K462Vfs*33 | Frame Shift Del (DEL) | VAF 50/157 reads (32%) | called by mutect2, pindel, varscan2
- UNC5A | c.2162G>A p.S721N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 73/228 reads (32%) | called by muse, mutect2, varscan2
- ZFPL1 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 70/189 reads (37%) | called by muse, mutect2, varscan2
- ZNF185 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ZNF200 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ZNF765 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ABCA7 | c.2325C>T p.C775= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs771423478; called by muse, mutect2, varscan2
- ADAMTS7 | c.2340G>T p.T780= | Silent (SNP) | VAF 166/515 reads (32%) | catalogued as COSV101182994; called by muse, mutect2, varscan2
- ANKRD24 | c.1611C>T p.T537= | Silent (SNP) | VAF 149/503 reads (30%) | called by muse, mutect2, varscan2
- ASB18 | c.639C>G p.R213= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2166C>T p.A722= | Silent (SNP) | VAF 83/200 reads (42%) | catalogued as rs764770295; called by muse, mutect2, varscan2
- FAM172A | c.178C>T p.L60= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV67936404; called by muse, mutect2, varscan2
- GNPTAB | c.1908G>A p.R636= | Silent (SNP) | VAF 107/283 reads (38%) | catalogued as COSV100172159; called by muse, mutect2, varscan2
- KANK3 | c.1839G>A p.A613= | Silent (SNP) | VAF 118/519 reads (23%) | catalogued as rs368061289, COSV58360783; called by muse, mutect2, varscan2
- KLK12 | c.564C>T p.G188= | Silent (SNP) | VAF 184/702 reads (26%) | catalogued as rs145723658; called by muse, mutect2, varscan2
- LRIT3 | c.1215C>G p.P405= | Silent (SNP) | VAF 94/279 reads (34%) | called by muse, mutect2, varscan2
- MTFR1 | c.576G>A p.P192= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as rs770323230; called by muse, mutect2, varscan2
- MYH6 | c.4083C>T p.R1361= | Silent (SNP) | VAF 32/328 reads (10%) | catalogued as rs568275249, COSV62449434; called by muse, mutect2
- OPLAH | c.864G>A p.S288= | Silent (SNP) | VAF 86/269 reads (32%) | catalogued as rs1554759938, COSV70679130; called by muse, mutect2, varscan2
- OR8J3 | c.838T>C p.L280= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- SCN10A | c.2973G>A p.P991= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs201397469; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIPA1L3 | c.3849C>T p.S1283= | Silent (SNP) | VAF 59/215 reads (27%) | catalogued as rs761002860, COSV55924999; called by muse, mutect2, varscan2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 87/342 reads (25%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- SON | c.2874A>C p.L958= | Silent (SNP) | VAF 76/221 reads (34%) | called by muse, mutect2, varscan2
- TRMT6 | c.567C>T p.A189= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs759809544; called by muse, mutect2, varscan2
- TTC6 | c.2556T>C p.D852= | Silent (SNP) | VAF 71/178 reads (40%) | catalogued as rs1363199747; called by muse, mutect2, varscan2
- USH2A | c.3735A>G p.R1245= | Silent (SNP) | VAF 76/228 reads (33%) | called by muse, mutect2, varscan2
- ZNFX1 | c.4287C>T p.V1429= | Silent (SNP) | VAF 105/430 reads (24%) | called by muse, mutect2, varscan2
- ABCC5 | c.3694+237G>A | Intron (SNP) | VAF 90/309 reads (29%) | catalogued as rs760020200; called by muse, mutect2, varscan2
- AIRE | c.*14G>A | 3'UTR (SNP) | VAF 149/472 reads (32%) | called by muse, mutect2, varscan2
- ATP8B3 | c.1552+95G>A | Intron (SNP) | VAF 59/207 reads (29%) | called by muse, mutect2, varscan2
- CD37 | c.343-174G>A | Intron (SNP) | VAF 35/141 reads (25%) | catalogued as rs1210480550; called by muse, mutect2, varscan2
- COBLL1 | c.344+70C>T | Intron (SNP) | VAF 13/69 reads (19%) | catalogued as rs754831585; called by muse, mutect2, varscan2
- CYP39A1 | c.*10G>C | 3'UTR (SNP) | VAF 17/58 reads (29%) | catalogued as rs1351642807; called by muse, varscan2
- DOCK4 | c.2736+3936C>T | Intron (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- LFNG | chr7:2528892 G>A | 3'Flank (SNP) | VAF 10/38 reads (26%) | catalogued as rs562235848, COSV56069254; called by muse, mutect2, varscan2
- LINC00479 | n.492C>T | RNA (SNP) | VAF 61/201 reads (30%) | called by muse, mutect2, varscan2
- MICAL1 | c.2305-47G>C | Intron (SNP) | VAF 70/293 reads (24%) | called by muse, mutect2
- RNU7-115P | chr17:64821949 C>T | 3'Flank (SNP) | VAF 218/630 reads (35%) | catalogued as rs755561023; called by muse, varscan2
- RPL27A | c.-1C>G | 5'UTR (SNP) | VAF 45/154 reads (29%) | catalogued as rs754250435; called by muse, mutect2, varscan2
- RPS21 | c.114+83G>A | Intron (SNP) | VAF 24/110 reads (22%) | catalogued as rs1422411816; called by muse, mutect2, varscan2
- SPAG6 | c.-32G>C | 5'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- SPINK5 | c.475-411T>C | Intron (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- WDR49 | c.487-6642A>C | Intron (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100393346; called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836439 C>T | 3'Flank (SNP) | VAF 48/188 reads (26%) | catalogued as rs759235923; called by muse, mutect2, varscan2
